Somatic mutation profile of tumor specimen TCGA-QK-A6V9-01A (aliquot TCGA-QK-A6V9-01A-11D-A34J-08) from TCGA case TCGA-QK-A6V9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 56.0 years (20,461 days).
Specimen TCGA-QK-A6V9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78c6c5aa-3692-4cfe-884e-dc4644cb1888.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6V9-10B (Blood Derived Normal), aliquot TCGA-QK-A6V9-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/177806d1-239b-43c9-9bfe-dc88db424560

The open-access MAF lists 86 somatic variants for this specimen: 54 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 27, Nonsense Mutation 6, Intron 3, 3'UTR 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913482, CM950469, COSV53390662; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 26/78 reads (33%) | hotspot (GDC flag); catalogued as rs121913305, CM941206, COSV57294317, COSV99923811; ClinVar: pathogenic; called by muse, varscan2
- ADAM29 | c.1575C>A p.N525K | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100822257; called by muse, mutect2, varscan2
- AHNAK | c.10714C>A p.L3572M | Missense Mutation (SNP) | VAF 95/363 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs368054244; called by muse, mutect2, varscan2
- ANKRD50 | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV101539054; called by muse, mutect2, varscan2
- ANXA6 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100637111; called by muse, mutect2
- ARID2 | c.4076A>G p.N1359S | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV57608666; called by muse, mutect2, varscan2
- ASPM | c.8378T>C p.M2793T | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as CD091977, COSV99661167; called by muse, mutect2, varscan2
- ATN1 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV100755964; called by muse, mutect2, varscan2
- ATP5F1B | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs747376704, COSV51636439; called by muse, mutect2, varscan2
- AUTS2 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV100717110; called by muse, mutect2, varscan2
- BRINP3 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 97/364 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100819524, COSV100819608; called by muse, mutect2, varscan2
- C5orf22 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57597942; called by muse, mutect2, varscan2
- CA9 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1374842744, COSV100999909; called by muse, mutect2, varscan2
- CBFA2T2 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100656537; called by muse, mutect2, varscan2
- CCNF | c.1009T>C p.C337R | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99564202; called by muse, mutect2, varscan2
- CKAP4 | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as rs374979802; called by muse, mutect2, varscan2
- CLASP2 | c.3154G>C p.E1052Q (on ENST00000359576; = p.E1051Q on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100224418; called by muse, mutect2, varscan2
- CYP27C1 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as rs779696383, COSV58869100; called by muse, mutect2, varscan2
- CYTIP | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 7/94 reads (7%) | catalogued as rs775465037, COSV99938912; called by muse, mutect2
- FCRL3 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as rs751894134, COSV100943572; called by muse, mutect2, varscan2
- GUF1 | c.334C>T p.R112* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as rs758730587, COSV99877489; called by muse, mutect2
- HCN1 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100302516; called by muse, mutect2, varscan2
- HS2ST1 | c.660C>G p.F220L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100777862; called by muse, mutect2, varscan2
- IGSF3 | c.2531C>A p.T844N (on ENST00000369486 / NM_001007237.3; = p.T864N on NM_001542.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as COSV100605133; called by muse, mutect2, varscan2
- IRF8 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs1242802767, COSV99236873; called by muse, mutect2, varscan2
- IRS4 | c.2641C>A p.P881T | Missense Mutation (SNP) | VAF 125/317 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1237531768, COSV100929745; called by muse, mutect2, varscan2
- LPIN3 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs749018950, COSV100182833; called by muse, mutect2, varscan2
- MAP3K14 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100766569; called by muse, mutect2, varscan2
- MCTP1 | c.1789G>A p.V597I | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV56521118; called by muse, mutect2, varscan2
- MECOM | c.2342G>A p.R781H (on ENST00000468789 / NM_001105078.4; = p.R969H on NM_004991.4) | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52961084; called by muse, mutect2
- OR2D3 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV53493101; called by muse, mutect2, varscan2
- PATZ1 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 9/28 reads (32%) | catalogued as COSV53229102; called by muse, mutect2, varscan2
- PIGX | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99582687; called by muse, mutect2, varscan2
- PITPNM2 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs764551528, COSV54910160; called by mutect2, varscan2
- PKHD1 | c.5146G>A p.V1716I | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs751058491, COSV61868269; called by muse, mutect2, varscan2
- RALBP1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192859734, COSV99192042; called by muse, mutect2
- RBMX2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 92/128 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100564856; called by muse, mutect2, varscan2
- RLF | c.1346A>C p.N449T | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101035717; called by muse, mutect2, varscan2
- SHKBP1 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs925915537, COSV99399425; called by muse, mutect2, varscan2
- SLC44A2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs752432975, COSV59836300; called by muse, mutect2, varscan2
- SYDE2 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV52315603; called by muse, mutect2, varscan2
- TAS2R60 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as COSV100223676; called by muse, mutect2, varscan2
- THNSL2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs964320373, COSV59084671; called by muse, mutect2, varscan2
- TNPO1 | c.2680G>A p.A894T | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100474067; called by muse, mutect2, varscan2
- USP10 | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.166); catalogued as COSV99551859; called by muse, mutect2, varscan2
- USP36 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs747977802, COSV100361861; called by muse, mutect2, varscan2
- WDR20 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1441326840, COSV100085502; called by muse, mutect2, varscan2
- ZNF208 | c.3038C>T p.S1013L | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV101237218; called by muse, mutect2, varscan2
- ZNF326 | c.604C>T p.R202* | Nonsense Mutation (SNP) | VAF 19/111 reads (17%) | catalogued as COSV61034692; called by muse, mutect2, varscan2
- ZNF816 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 80/545 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV99554722; called by muse, mutect2, varscan2
- GAS6 | c.624_625del p.E209Gfs*15 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, pindel, varscan2
- PRKAB2 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- VWF | c.8219dup p.S2741Vfs*2 | Frame Shift Ins (INS) | VAF 25/99 reads (25%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.2217G>A p.T739= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs919366480, COSV99926949; called by muse, mutect2, varscan2
- APOF | c.126G>A p.Q42= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as rs1020730653, COSV100029154; called by muse, mutect2, varscan2
- ASB16 | c.168C>T p.C56= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99519058; called by muse, mutect2
- BCAP31 | c.579C>T p.D193= | Silent (SNP) | VAF 71/242 reads (29%) | catalogued as rs141341467, COSV100799007; ClinVar: likely benign; called by muse, mutect2, varscan2
- CAP1 | c.1152C>T p.D384= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as rs749068331, COSV100472711; called by muse, mutect2, varscan2
- CELSR2 | c.1800C>T p.V600= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99604789; called by muse, mutect2, varscan2
- CHAC1 | c.36C>T p.P12= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs768070059, COSV101471083; called by muse, mutect2, varscan2
- CHRM4 | c.213C>G p.L71= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs200009704, COSV100708884; called by muse, mutect2, varscan2
- CNTNAP1 | c.1113C>T p.F371= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs1254716843, COSV52847801; called by muse, mutect2, varscan2
- DPP3 | c.1179C>T p.P393= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs202241881, COSV100855746; called by muse, mutect2, varscan2
- EIF4A3 | c.441C>T p.G147= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs770103058, COSV53920918; called by muse, mutect2, varscan2
- EML3 | c.1533C>T p.H511= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs150541468, COSV99604413; called by muse, mutect2, varscan2
- ENOPH1 | c.588T>C p.I196= | Silent (SNP) | VAF 10/154 reads (6%) | catalogued as COSV99908827; called by muse, mutect2
- FASTK | c.792C>T p.F264= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs752586309, COSV99879997; called by muse, mutect2, varscan2
- FBXO24 | c.459G>A p.G153= (on ENST00000241071 / NM_033506.3; = p.G191= on NM_012172.5) | Silent (SNP) | VAF 43/149 reads (29%) | catalogued as COSV53826489; called by muse, mutect2, varscan2
- GALNT8 | c.159C>T p.Y53= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as rs749316788, COSV52897174; called by muse, mutect2, varscan2
- IL4I1 | c.210C>T p.A70= | Silent (SNP) | VAF 58/320 reads (18%) | catalogued as rs753062978, COSV62011940; called by muse, mutect2, varscan2
- MAP4K4 | c.1488C>T p.C496= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1233086110; called by muse, mutect2
- P4HB | c.573C>T p.D191= | Silent (SNP) | VAF 114/385 reads (30%) | catalogued as rs141223466; called by muse, mutect2, varscan2
- PHF20 | c.1224G>A p.T408= | Silent (SNP) | VAF 64/287 reads (22%) | catalogued as rs984470006, COSV59185378; called by muse, mutect2, varscan2
- SLC25A10 | c.735G>A p.A245= | Silent (SNP) | VAF 94/316 reads (30%) | catalogued as rs770024783, COSV58971856; called by mutect2, varscan2
- SMAD1 | c.432C>T p.S144= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs766290015, COSV57470963; called by muse, mutect2, varscan2
- SYNPO2 | c.2469C>T p.N823= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as rs1158917860, COSV61112968; called by muse, mutect2, varscan2
- TBL1Y | c.534C>T p.H178= | Silent (SNP) | VAF 28/50 reads (56%) | catalogued as rs754716880, COSV60733486; called by muse, mutect2, varscan2
- TFPT | c.208C>A p.R70= | Silent (SNP) | VAF 25/235 reads (11%) | catalogued as COSV100320133; called by muse, mutect2, varscan2
- TIFA | c.132C>T p.S44= | Silent (SNP) | VAF 84/329 reads (26%) | catalogued as rs942451428, COSV100655747; called by muse, varscan2
- USP4 | c.993C>T p.L331= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV99649800; called by muse, mutect2
- FGFR3 | c.*1061C>G | 3'UTR (SNP) | VAF 28/70 reads (40%) | catalogued as rs1490564667, COSV99603549; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIWIL2 | c.-2C>G | 5'UTR (SNP) | VAF 20/75 reads (27%) | catalogued as COSV100769554; called by muse, mutect2, varscan2
- PRR22 | c.193+139G>A | Intron (SNP) | VAF 18/329 reads (5%) | catalogued as rs776534729, COSV100288506; called by muse, mutect2
- TMC5 | c.1049-3317G>A | Intron (SNP) | VAF 21/66 reads (32%) | catalogued as rs758133692, COSV99572434; called by muse, mutect2, varscan2
- VKORC1 | c.173+246G>A | Intron (SNP) | VAF 87/273 reads (32%) | catalogued as rs746107668, COSV100161864; called by muse, mutect2, varscan2
